Surgical pathology report (de-identified scan), TCGA case TCGA-08-0351, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0351-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

TCGA-08-0351

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, "MRS1," biopsy: WHO anaplastic astrocytoma, grade III.
- B. Brain, biopsy: WHO glioblastoma multiforme, grade IV; see comment.

COMMENT: This glioblastoma multiforme is best demonstrated on section B2 where there are areas of moderate-to-high cellularity with marked nuclear and cytoplasmic pleomorphism, accompanied by foci of microvascular proliferation. Multiple mitotic figures are identified, but no foci of necrosis are present. An immunoperoxidase stain for GFAP on section B2 is positive in the neoplastic astrocytes. An immunoperoxidase stain for MIB-1 will be performed on section B2 and an addendum will follow.

Gross Description

The specimen is received in formalin in two parts, each labeled with the patient's name and medical record number.

Part A, designated [REDACTED] consists of a single piece of soft, white tissue that measures 0.3 x 0.2 x <0.1 cm. The specimen is entirely submitted in cassette A1.

Part B, designated "tumor," consists of multiple pieces of tan-white and red, soft tissue that measure 2.5 x 1.5 x 0.7 cm in aggregate. The tissue is sectioned and submitted in toto in cassettes B1-B3.

Clinical History

The patient is a [REDACTED] with history of [REDACTED] with an astrocytoma.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[page 2 of 2]
ADDENDUM**Date of Addendum:** **Addendum Comment**

The MIB-1 immunohistochemical labelling is 7.90%.

Source: NCI Genomic Data Commons file c9aee39f-cd0e-41dd-b6e6-1152b46a31da (TCGA-08-0351.9126EF3C-2131-4726-B711-77F07F9069B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).